Somatic mutation profile of tumor specimen 0DGRHK from CCDI case PBBTMS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.6 years (3,509 days).
Specimen 0DGRHK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d760dc71-87db-405d-ac5b-81d9665ffc40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGRHV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa63f977-7489-4a40-9eee-6cea1d787f51

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH14 | c.5345G>A p.R1782H (on ENST00000445597; = p.R2187H on NM_001367479.1) | Missense Mutation (SNP) | VAF 230/1615 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as rs1398519703; called by muse, mutect2, varscan2
- EFL1 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 186/1034 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1490948273, COSV51602569; called by muse, mutect2, varscan2
- PADI2 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 64/1304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279407277; called by muse, mutect2
- TCTE1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 346/584 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV65255582, COSV65255590; called by muse, varscan2
- ZNF277 | c.53A>T p.D18V | Missense Mutation (SNP) | VAF 98/2182 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs748395240; called by muse, mutect2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 22/900 reads (2%) | called by muse, mutect2
- NCOR2 | c.7062G>C p.W2354C | Missense Mutation (SNP) | VAF 135/602 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SUV39H2 | c.380T>C p.I127T (on ENST00000354919 / NM_001193424.2; = p.I67T on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 612/1352 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, varscan2
- DOK6 | c.399G>C p.R133= | Silent (SNP) | VAF 212/822 reads (26%) | catalogued as COSV66934178; called by muse, mutect2, varscan2
- FRMPD2 | c.3663G>T p.L1221= | Silent (SNP) | VAF 89/507 reads (18%) | called by muse, mutect2, varscan2
- SIGLEC16 | c.552C>T p.D184= | Silent (SNP) | VAF 72/623 reads (12%) | catalogued as rs748815436; called by muse, mutect2, varscan2
- SPCS1 | c.114G>A p.Q38= | Silent (SNP) | VAF 38/450 reads (8%) | called by muse, mutect2
- CYP4F11 | c.344-92A>G | Intron (SNP) | VAF 13/58 reads (22%) | catalogued as rs984147339; called by muse, mutect2, varscan2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 13/296 reads (4%) | called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as COSV55814242; called by muse, mutect2
- SLC2A11 | c.1291-18G>A | Intron (SNP) | VAF 60/1155 reads (5%) | catalogued as rs779367467; called by muse, mutect2
